Somatic mutation profile of tumor specimen 0DPSNP from CCDI case PBCDYU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sex cord-gonadal stromal tumor, NOS; Tissue or organ of origin: Ovary; Age at diagnosis: 14.9 years (5,454 days).
Specimen 0DPSNP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f69fc2b-7166-44a6-8497-454a067bfcb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPSN4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80df29ce-83f6-4d70-a565-a9f6882cfeba

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 1, 3'UTR 1, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 31/260 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, mutect2, varscan2
- LAMC3 | c.2918C>T p.A973V | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.006); called by mutect2, varscan2
- PISD | c.326C>T p.A109V (on ENST00000439502 / NM_001326412.1; = p.A75V on NM_014338.3) | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PNPLA3 | c.979+1G>T p.X327_splice | Splice Site (SNP) | VAF 39/166 reads (23%) | called by muse, mutect2, varscan2
- PRAME | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 81/391 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RXFP2 | c.629A>T p.Q210L | Missense Mutation (SNP) | VAF 68/404 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by muse, varscan2
- TCTN2 | c.911G>A p.C304Y | Missense Mutation (SNP) | VAF 47/281 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM83E | c.1377G>A p.E459= | Silent (SNP) | VAF 21/138 reads (15%) | called by muse, mutect2, varscan2
- CDKL4 | c.928-98C>G | Intron (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2, varscan2
- MGAM2 | c.*62G>C | 3'UTR (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
